MMRF case MMRF_2012 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/39bfe159-bbf1-45cb-8bc9-eeb5b4b3016c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.5 years (22,827 days); ISS stage: II; Days to last known disease status: 990 days (2.7 years); Days to last follow up: 990 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 39 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 325 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 39 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 216 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 39 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 4.83 µg/mL; Hemoglobin 4.22 mmol/L; Leukocytes 3.3 ×10⁹/L; Platelets 367 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 29 g/L; Total Protein 9.7 g/dL; Glucose 5.12 mmol/L.
- Day 93: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.57 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 5.97 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 4.4 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 7.13 ×10⁹/L; Platelets 406 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 176 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.36 mg/dL; Immunoglobulin G 9.14 g/L; Immunoglobulin A 6.02 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 4.4 mmol/L; Leukocytes 10.1 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 1.63 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 4.73 mmol/L.
- Day 267 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.18 mg/dL; Immunoglobulin G 9.18 g/L; Immunoglobulin A 7.01 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 5.27 µkat/L; Hemoglobin 4.15 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 434 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 351 (ECOG 1): Hemoglobin 4.59 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 4.62 mmol/L.
- Day 432 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.5 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 12.2 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 4.34 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.06 ×10⁹/L; Platelets 431 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 5.23 mmol/L.
- Day 537: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.3 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 9.6 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 3.78 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 6.04 ×10⁹/L; Platelets 334 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 4.62 mmol/L.
- Day 630: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.1 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 9.91 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 4.9 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 6.15 ×10⁹/L; Platelets 388 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 4.46 mmol/L.
- Day 711 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.2 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 9.1 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.03 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.03 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 9.46 mmol/L.
- Day 837 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 906 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.2 mg/dL; Hemoglobin 4.9 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.41 ×10⁹/L; Platelets 376 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 990 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.52 mg/dL; Immunoglobulin G 8.22 g/L; Immunoglobulin A 7.63 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 5.62 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 1.95 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -4: Weight: 45 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2012_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2012_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
